Somatic mutation profile of tumor specimen d7608884-a0d6-4e9e-aac7-6cd813 (aliquot d7608884-a0d6-4e9e-aac7-6cd813_D6_1) from CPTAC case 05CO049, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen d7608884-a0d6-4e9e-aac7-6cd813: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16fe8b68-c3be-4e07-81b3-42e25fc94e94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 68f33ff4-7bd8-4464-b00b-a3106b (Blood Derived Normal), aliquot 68f33ff4-7bd8-4464-b00b-a3106b_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca5a48e0-469b-4460-af71-979021dbcfc4

The open-access MAF lists 185 somatic variants for this specimen: 126 protein-altering or splice-affecting, 41 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 41, Nonsense Mutation 12, Intron 9, Splice Site 5, 3'Flank 3, RNA 3, 5'UTR 2, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7327C>T p.R2443* | Nonsense Mutation (SNP) | VAF 61/320 reads (19%) | catalogued as rs121434220, CM960104, COSV53724743, COSV53745412; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- LAMA2 | c.3829C>T p.R1277* | Nonsense Mutation (SNP) | VAF 66/512 reads (13%) | catalogued as rs1554269891, COSV70354446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1060500766, CM158378, COSV59284912, COSV59287883; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs770383355; called by muse, mutect2
- ABCC2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs572309746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMDEC1 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 26/192 reads (14%) | catalogued as rs1434377951, COSV56476584; called by muse, mutect2, varscan2
- APC | c.3980C>A p.S1327* | Nonsense Mutation (SNP) | VAF 73/408 reads (18%) | catalogued as COSV57323640, COSV57335489, COSV57371230; called by muse, mutect2, varscan2
- ASIC5 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs750030175; called by muse, mutect2, varscan2
- ATP8A2 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs190982690; called by muse, mutect2, varscan2
- BMPR2 | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.055); catalogued as rs147960425; called by muse, mutect2
- C6orf52 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs867864371, COSV99468488; called by muse, mutect2, varscan2
- CAPN10 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54376113; called by muse, mutect2, varscan2
- CBFB | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52002880; called by muse, mutect2, varscan2
- CD1A | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs140989108, COSV56860759; called by muse, mutect2, varscan2
- CHRNA5 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148722844, COSV104409151; called by muse, mutect2
- CIITA | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as rs370673632; called by muse, mutect2, varscan2
- CNTNAP5 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs751028037, COSV70476456; called by muse, varscan2
- COL5A3 | c.4739C>T p.A1580V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs556102205; called by muse, mutect2, varscan2
- COQ10A | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.274); catalogued as rs771479544; called by muse, mutect2, varscan2
- DCAF4L2 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 21/232 reads (9%) | catalogued as COSV60476493; called by muse, mutect2
- EVC | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560291426, COSV53835840; called by muse, mutect2, varscan2
- EVC2 | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs752385254; called by muse, mutect2
- GIGYF2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs758445866, COSV65249171; called by muse, mutect2, varscan2
- GPR161 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV54792617; called by muse, mutect2, varscan2
- GRAP | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs771901263; called by muse, mutect2, varscan2
- GSR | c.940C>G p.P314A | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV55323371; called by muse, mutect2, varscan2
- IKBKB | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1366003386, COSV60599626; called by muse, mutect2, varscan2
- INTS4 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.182); catalogued as rs1410122615; called by muse, mutect2, varscan2
- ITGA5 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143754928, COSV53215878; called by muse, varscan2
- KRT75 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs768161259; called by muse, mutect2, varscan2
- LINGO3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs774489067, COSV68261946; called by muse, mutect2, varscan2
- LOXHD1 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs570602921, COSV56060084; called by muse, mutect2, varscan2
- MAFK | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as rs752326077; called by muse, mutect2, varscan2
- MAGEC1 | c.1746G>T p.Q582H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.948); catalogued as COSV53577548, COSV99594763; called by muse, mutect2, varscan2
- METTL9 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs756894266; called by muse, mutect2, varscan2
- MOB3A | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs199687461; called by muse, mutect2, varscan2
- MYH2 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99819232; called by muse, mutect2, varscan2
- NELL1 | c.1933C>A p.Q645K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs891287869; called by muse, mutect2, varscan2
- NPAS2 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458141720, COSV59558449; called by muse, mutect2
- NPR3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV54091475; called by muse, mutect2, varscan2
- OLAH | c.557T>C p.I186T (on ENST00000378228 / NM_001039702.3; = p.I239T on NM_018324.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.358); catalogued as rs1211239552; called by muse, mutect2, varscan2
- OR4K14 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV59294297; called by muse, mutect2, varscan2
- OR8B8 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100045242; called by muse, mutect2
- PCDH11X | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014247; called by muse, varscan2
- PCMTD2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs756506348, COSV104382951; called by muse, mutect2
- PKD1 | c.9730C>T p.R3244C | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs146732153; called by muse, mutect2, varscan2
- PLXNA1 | c.5257G>A p.V1753M | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs757092586; called by muse, mutect2, varscan2
- PLXNB2 | c.415G>C p.G139R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV63780090, COSV63780141; called by muse, mutect2, varscan2
- PXDN | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53229593, COSV53233830; called by muse, mutect2, varscan2
- PXDN | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as rs1283491534; called by muse, mutect2
- RYR1 | c.6211C>T p.R2071W | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs147441124, COSV62091378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59514381; called by muse, mutect2, varscan2
- SDC2 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99043021; called by muse, mutect2
- SH3BGRL | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1370944844; called by muse, mutect2, varscan2
- SH3D19 | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs374070832; called by muse, mutect2, varscan2
- SMAD5 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 25/296 reads (8%) | catalogued as COSV72505711; called by muse, mutect2
- SYNE1 | c.9604C>T p.R3202C (on ENST00000367255 / NM_182961.4; = p.R3209C on NM_033071.3) | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749550071, COSV54977040; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SYT10 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as rs771869540; called by muse, mutect2, varscan2
- TBPL2 | c.1117A>T p.K373* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as rs767811298, COSV55955610; called by muse, mutect2, varscan2
- TTF1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1048742218; called by muse, mutect2
- WDR87 | c.5398C>T p.R1800W | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs369489743; called by muse, mutect2, varscan2
- WFDC12 | c.172del p.E58Kfs*14 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as COSV65661316; called by mutect2, pindel, varscan2
- XKR4 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs931462398, COSV59311222; called by muse, varscan2
- ZNF534 | c.745C>A p.H249N (on ENST00000332323 / NM_001143939.3; = p.H236N on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56516706; called by muse, mutect2, varscan2
- ZNF716 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 18/144 reads (13%) | catalogued as rs1554324926; called by mutect2, varscan2
- ACTN3 | c.1576C>A p.L526M | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRE5 | c.2149_2150insGACGGA p.W716_K717insRR (on ENST00000242786 / NM_078481.4; = p.W623_K624insRR on NM_001784.5) | In Frame Ins (INS) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2384-1G>A p.X795_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- ASTN1 | c.3815T>C p.L1272P | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ATIC | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCDC168 | c.18701A>G p.N6234S | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.042); called by mutect2, varscan2
- CCHCR1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CENPI | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COLGALT2 | c.687C>A p.C229* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- CRAMP1 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, varscan2
- DENND2A | c.3011A>T p.K1004I | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- DNAH5 | c.10436C>A p.A3479E | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- EED | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- EIF2B5 | c.320+2T>C p.X107_splice | Splice Site (SNP) | VAF 32/284 reads (11%) | called by mutect2, varscan2
- EIF4A3 | c.803T>A p.L268Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- EOGT | c.373A>T p.R125* | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- FBXW7 | c.1087dup p.T363Nfs*2 (on ENST00000281708 / NM_001349798.2; = p.T283Nfs*2 on NM_018315.5) | Frame Shift Ins (INS) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- FSTL5 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GPNMB | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GRIK1 | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- H2AC17 | c.283A>T p.N95Y | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- HOXC13 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- HTRA2 | c.647A>C p.Y216S | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGFBP3 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- KMT2A | c.4621C>G p.P1541A | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMB1 | c.5192C>G p.A1731G | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGAT4C | c.1353T>A p.F451L | Missense Mutation (SNP) | VAF 41/410 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- MYO1A | c.1086T>G p.N362K | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NBEA | c.7563G>T p.L2521F | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- NPAS3 | c.418G>T p.A140S (on ENST00000356141 / NM_001164749.2; = p.A108S on NM_022123.3) | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- OR13H1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, varscan2
- OR5L1 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2
- OXR1 | c.679-1G>A p.X227_splice (on ENST00000442977 / NM_001198532.1; = p.X226_splice on NM_018002.3) | Splice Site (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- PDS5B | c.3395G>A p.G1132E | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PKD1L1 | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2
- PLA2G1B | c.323-1G>T p.X108_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- PLCD1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLN | c.1595T>A p.I532N | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR12 | c.2324C>A p.T775K (on ENST00000615927; = p.T1596K on NM_020719.3) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RGS11 | c.1090G>A p.A364T (on ENST00000397770 / NM_183337.3; = p.A343T on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- RIMS1 | c.3404G>C p.R1135T | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- ROCK1 | c.1291A>C p.T431P | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SLC15A4 | c.1090-1G>T p.X364_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- SLC22A23 | c.558_566del p.S187_P189del | In Frame Del (DEL) | VAF 18/124 reads (15%) | called by pindel, varscan2
- SLC4A10 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2
- SLITRK4 | c.103G>C p.V35L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SNAPC3 | c.848G>T p.R283I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SNAPC3 | c.849A>T p.R283S | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SNX6 | c.116A>C p.Q39P (on ENST00000652385; = p.Q27P on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- STAT6 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGIF1 | c.502_505del p.L168Afs*15 (on ENST00000330513 / NM_001374396.1; = p.L188Afs*15 on NM_003244.4) | Frame Shift Del (DEL) | VAF 15/150 reads (10%) | called by mutect2, pindel, varscan2
- TNRC6B | c.3282dup p.F1095Ifs*2 (on ENST00000454349 / NM_001162501.2; = p.F1042Ifs*2 on NM_015088.3) | Frame Shift Ins (INS) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 47/312 reads (15%) | called by muse, mutect2, varscan2
- TRPS1 | c.3179G>A p.G1060E (on ENST00000220888 / NM_001330599.2; = p.G1073E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/613 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC80 | c.6965A>C p.K2322T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WBP2 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, varscan2
- ZNF765 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by mutect2, varscan2
- ZNF83 | c.329T>G p.I110R | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ADAMTSL2 | c.645C>T p.H215= | Silent (SNP) | VAF 35/269 reads (13%) | catalogued as rs772372827, COSV63204188; called by muse, mutect2, varscan2
- ARID2 | c.3039A>G p.Q1013= | Silent (SNP) | VAF 39/250 reads (16%) | called by muse, mutect2, varscan2
- ATPAF2 | c.279G>A p.E93= | Silent (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2, varscan2
- BICRA | c.78C>T p.S26= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs200233936, COSV67605158; called by muse, varscan2
- C1orf53 | c.36C>T p.A12= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs1313662690; called by muse, mutect2, varscan2
- CACNA1A | c.7524C>T p.D2508= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1269668562; called by muse, mutect2, varscan2
- CLASRP | c.1347C>T p.D449= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs1437082335; called by muse, mutect2
- CNNM1 | c.2538C>T p.D846= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs116405851; called by muse, mutect2, varscan2
- CYB5D2 | c.189C>T p.V63= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- CYP2D7 | c.714C>A p.G238= | Silent (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.72G>A p.P24= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as rs984865037; called by muse, mutect2, varscan2
- DIS3 | c.1086G>A p.K362= | Silent (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- DRD5 | c.855C>T p.R285= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs201697048, COSV58577368; called by muse, mutect2, varscan2
- FBN2 | c.7422C>T p.C2474= | Silent (SNP) | VAF 14/250 reads (6%) | catalogued as rs1223904235, COSV52542835; called by muse, mutect2
- HPDL | c.474C>T p.V158= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- HYDIN | c.14544G>A p.A4848= | Silent (SNP) | VAF 22/235 reads (9%) | catalogued as rs373475539; called by muse, mutect2, varscan2
- ICE1 | c.1635A>G p.E545= | Silent (SNP) | VAF 38/359 reads (11%) | called by muse, mutect2, varscan2
- IGLV3-27 | c.117C>T p.I39= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- KCTD3 | c.330C>G p.L110= | Silent (SNP) | VAF 27/251 reads (11%) | called by muse, mutect2, varscan2
- LIMD1 | c.519C>T p.C173= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as rs1215217009; called by muse, mutect2
- MAPRE3 | c.348C>T p.D116= | Silent (SNP) | VAF 32/255 reads (13%) | catalogued as rs758271746; called by muse, mutect2, varscan2
- MYO7B | c.4434C>T p.Y1478= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs370830130; called by muse, mutect2, varscan2
- NAALAD2 | c.1416C>A p.P472= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- NDUFS2 | c.805C>A p.R269= | Silent (SNP) | VAF 30/232 reads (13%) | catalogued as COSV57156409; called by muse, mutect2, varscan2
- OR10R2 | c.90C>T p.T30= | Silent (SNP) | VAF 34/290 reads (12%) | catalogued as rs374772772; called by muse, mutect2, varscan2
- OR56B4 | c.873C>A p.L291= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- PCDHA13 | c.1542C>T p.S514= | Silent (SNP) | VAF 26/366 reads (7%) | catalogued as COSV56478102; called by muse, mutect2
- PLCD1 | c.1038C>T p.D346= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as rs371718392, COSV52186444; called by muse, mutect2, varscan2
- PLEKHF1 | c.606C>T p.R202= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs758935138; called by muse, varscan2
- POTEC | c.1413C>T p.D471= | Silent (SNP) | VAF 24/276 reads (9%) | catalogued as rs755821779; called by muse, mutect2, varscan2
- PRSS1 | c.675G>A p.K225= | Silent (SNP) | VAF 27/228 reads (12%) | catalogued as rs375871958; called by muse, mutect2, varscan2
- ROR1 | c.1305G>A p.S435= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as rs768590709, COSV64284917; called by muse, mutect2
- SCN9A | c.561G>A p.P187= | Silent (SNP) | VAF 44/362 reads (12%) | catalogued as rs200182914; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCHH | c.5290C>T p.L1764= | Silent (SNP) | VAF 37/520 reads (7%) | called by muse, mutect2
- TEP1 | c.5257C>T p.L1753= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- TMCC2 | c.426C>T p.P142= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs140397839; called by muse, mutect2, varscan2
- TRPC4 | c.2520C>T p.T840= (on ENST00000379705 / NM_016179.4; = p.T845= on NM_003306.3) | Silent (SNP) | VAF 97/398 reads (24%) | catalogued as rs1166309569, COSV58999040; called by mutect2, varscan2
- TRPM1 | c.2073C>T p.D691= | Silent (SNP) | VAF 46/446 reads (10%) | catalogued as rs371439326; called by muse, mutect2
- TSPYL6 | c.153G>A p.P51= | Silent (SNP) | VAF 17/181 reads (9%) | catalogued as rs761886975, COSV100336729; called by muse, mutect2
- ULBP2 | c.429C>T p.F143= | Silent (SNP) | VAF 37/254 reads (15%) | catalogued as rs780818906; ClinVar: likely benign; called by muse, mutect2, varscan2
- XRRA1 | c.1848C>T p.H616= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as rs768787275; called by muse, mutect2
- AGBL3 | c.1841+5136C>A | Intron (SNP) | VAF 29/196 reads (15%) | catalogued as COSV51957479; called by muse, mutect2, varscan2
- AL139039.3 | chr6:10509130 G>A | 3'Flank (SNP) | VAF 14/96 reads (15%) | catalogued as rs1306214806; called by muse, mutect2, varscan2
- C19orf12 | chr19:29701384 T>A | 3'Flank (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- C1orf115 | c.-11G>T | 5'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, varscan2
- CELF4 | c.658-45G>A | Intron (SNP) | VAF 12/150 reads (8%) | catalogued as rs771870803, COSV100611514; called by muse, mutect2
- DPP6 | c.*315G>A | 3'UTR (SNP) | VAF 25/201 reads (12%) | catalogued as COSV59628073; called by muse, mutect2, varscan2
- EIF4EBP1 | c.-10A>G | 5'UTR (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- EP400 | c.1335+1619C>T | Intron (SNP) | VAF 22/180 reads (12%) | catalogued as rs763258752; called by muse, mutect2, varscan2
- EYS | c.1767-6863G>A | Intron (SNP) | VAF 42/548 reads (8%) | called by muse, mutect2
- FKTN | c.1172+46A>G | Intron (SNP) | VAF 37/352 reads (11%) | called by muse, mutect2, varscan2
- GULP1 | c.843+1792G>A | Intron (SNP) | VAF 25/221 reads (11%) | catalogued as rs1386012956, COSV63066179; called by muse, mutect2, varscan2
- LRRC75B | chr22:24583775 G>T | 3'Flank (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2
- NRG1 | c.701-4779C>T | Intron (SNP) | VAF 32/215 reads (15%) | catalogued as rs1409611071; called by muse, mutect2, varscan2
- PGR | c.1907-54G>T | Intron (SNP) | VAF 14/214 reads (7%) | catalogued as rs1218730877; called by muse, mutect2
- RPL26P30 | n.739G>A | RNA (SNP) | VAF 40/202 reads (20%) | catalogued as rs781160123; called by muse, mutect2, varscan2
- SNORD116-27 | n.20G>T | RNA (SNP) | VAF 21/225 reads (9%) | called by muse, mutect2
- SRSF3 | c.380+29C>A | Intron (SNP) | VAF 20/136 reads (15%) | catalogued as COSV59670490; called by mutect2, varscan2
- SSPOP | n.15295G>A | RNA (SNP) | VAF 16/172 reads (9%) | catalogued as rs754025182, COSV65126867; called by muse, mutect2, varscan2
